Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A5XP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A5XP-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Pheochromocytoma NOS
8700/0
Site @ Adrenal gland NOS
C74.9

JW 4/3/13

Diagnosis:

A: Inferior mesenteric vein lymph node, biopsy

- Benign fibroadipose tissue; no lymph node identified; no tumor seen.

B: Adrenal gland, left, adrenalectomy

- Adrenal pheochromocytoma with atypical histologic features, raising concern for possible malignant clinical behavior (See Comment).

- Tumor size 3.8 x 2.9 x 2.7 cm.

- Vascular invasion identified, present at the en face vascular resection margin (B1).

- Tumor focally involves the peri-adrenal soft tissue resection margin (B3).

- Focal extension of tumor into peri-adrenal adipose tissue identified (B2, B3).

Comment:

The neoplasm demonstrates multiple atypical histologic features which have been shown to correlate with potential aggressive biologic behavior and raise concern for possible malignant clinical behavior. These features include the presence of vascular invasion, capsular invasion, extension into peri-adrenal adipose tissue, expanded large and confluent cellular nests, profound cellular and nuclear pleomorphism, nuclear hyperchromasia, and occasional macronucleoli. Close clinical followup is recommended.

Special stains support the diagnosis. The tumor demonstrates diffuse reactivity for synaptophysin and chromogranin. S-100 highlights scattered sustentacular cells with some disruption of the sustentacular cell network, and also shows variable moderate staining of tumor cells. Appropriate controls are performed.

The frozen section diagnosis is confirmed.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by Dr.
at

[page 2 of 3]
FSA1: Inferior mesenteric vein node, biopsy
- Benign adipose tissue

Drs. at

Frozen Section Pathologist:, MD

Clinical History:

-year-old female with adrenal mass, probable pheochromocytoma.

Gross Description:

Specimen A is received is one appropriately labeled container, received fresh for frozen section, and additionally labeled "inferior mesenteric vein node." It holds a yellow/tan soft tissue fragment that measures 0.8 x 0.5 x 0.2 cm. The fragment is entirely frozen as FSA1,

Specimen B:

Specimen fixation: Formalin

Type of specimen: Adrenalectomy

Side of specimen: Left

Size and weight of specimen: 6.7 x 5.3 x 2.8 cm, 47.0 grams, structures attached to the gland

Orientation: The entire soft tissue margin is inked blue.

Tumor site: Medulla

Tumor description: Medulla, pale tan to brown, focal hemorrhagic areas, focal necrosis. The tumor is well-circumscribed.

Tumor weight: Consists of approximately 80% of the specimen

Tumor size: 3.8 x 2.9 x 2.7 cm

Confinement/non-confinement to gland: Defer to light microscopy

Distance of tumor to surgical margin: Less than 1 mm from the blue inked soft tissue margin.

Appearance of adrenal gland away from tumor: Grossly unremarkable, cortex is 0.2 cm, medulla is 0.2 cm

[page 3 of 3]
Lymph nodes: N/A

Tissue submitted for special investigations: Tumor is submitted to tissue procurement foundation.

Digital picture: Not taken

Block Summary:

Inking: The entire soft tissue margin is inked blue

B1 - Vascular margin

B2 - Representative section of the tumor and normal adrenal gland

B3-B5 - Representative section of tumor, including closest approach to the margin

B6 - Gross uninvolved adrenal gland

Uncertain Malignant behavior. No staging.

Diagnosis Synchronous Primary Tumor		✓

Source: NCI Genomic Data Commons file 834285ab-0373-471d-8e54-0bb8f7bdf436 (TCGA-QT-A5XP.CCDF3A12-C70D-4379-B6B7-0682AE4AF97A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).